Gene-level copy-number profile of tumor specimen TCGA-CG-4455-01A from TCGA case TCGA-CG-4455, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 72.3 years (26,421 days).
Specimen TCGA-CG-4455-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.4a0504fa-099a-4e7a-847d-0803041b0bb3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CG-4455-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1e5ebb4c-13fc-4c78-bb25-1924dcd187dc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 178; copy number 2: 41,314; copy number 3: 15,289; copy number 4: 2,152; copy number 5: 298; copy number 6: 128; copy number 7: 128; copy number 10: 110; copy number 11: 2; copy number 13: 76; copy number 20: 16; copy number 28: 12; copy number 30: 53; copy number 39: 53.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CG-4455-01A-01D-1155-01): tumor purity 0.33, ploidy 2.95, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 876 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:91,264,433–102,464,863, 307 genes, copy number 6–13 (within-gene range 2–13) (broad region; genes not listed).
- chr11:58,748,999–59,310,576, 25 genes, copy number 7: AP000445.2, TMA16P1, GLYATL2, GLYATL1P2, GLYATL1, AP001652.1, AP001636.3, AP001636.2, GLYATL1P1, AP001636.1, GLYATL1P4, GLYATL1B, FAM111B, FAM111A-DT, AP001258.1, FAM111A, DTX4, MPEG1, RN7SL42P, WARS1P1, SLC25A47P1, AP002358.1, AP002358.2, RN7SL435P, OR5AN2P.
- chr11:68,707,440–70,436,584, 53 genes, copy number 11–30 (within-gene range 2–30): TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,604,859, 2 genes, copy number 30: AP001271.1, AP001271.2.
- chr12:57,253,762–70,543,040, 277 genes, copy number 5–39 (within-gene range 2–39) (broad region; genes not listed).
- chr20:87,250–8,043,512, 211 genes, copy number 5 (broad region; genes not listed).
- chr20:8,097,824–8,099,774, 1 gene, copy number 5: PHKBP1.

Autosomal genes at a single copy (total copy number 1): 143. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
